Somatic mutation profile of tumor specimen 0E1HFA from CCDI case PBCWJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0E1HFA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5165e84f-82e3-41df-8927-32286a300955.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E1HG4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe3fc51a-cca5-4bcc-9970-a33c9f9100f3

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1S | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 134/386 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs781932595, COSV61070116; called by muse, mutect2, varscan2
- MAP3K6 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 87/420 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs768560281, COSV100709474; called by muse, mutect2, varscan2
- PRDM6 | c.1558G>A p.V520M | Missense Mutation (SNP) | VAF 80/379 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs1348257038, COSV68336055; called by muse, mutect2, varscan2
- CDKN1C | c.622_659del p.P208Sfs*20 | Frame Shift Del (DEL) | VAF 112/194 reads (58%) | called by pindel, varscan2
- KCNQ3 | c.1422G>A p.T474= | Silent (SNP) | VAF 80/474 reads (17%) | catalogued as rs150803363, COSV66463130; called by muse, mutect2, varscan2
